Somatic mutation profile of tumor specimen TCGA-G9-6351-01A (aliquot TCGA-G9-6351-01A-21D-1961-08) from TCGA case TCGA-G9-6351, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.3 years (18,723 days).
Specimen TCGA-G9-6351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdfd039e-e6d5-4292-a4d8-7dc65f7f6a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6351-10A (Blood Derived Normal), aliquot TCGA-G9-6351-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7c9ee05-aaf1-410c-b63c-9a618457ee8a

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.4102G>A p.A1368T | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs767038879, COSV53242298; called by muse, mutect2, varscan2
- BRS3 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV65710936; called by muse, mutect2, varscan2
- FBXL17 | c.1835T>C p.I612T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV62852827; called by muse, mutect2, varscan2
- FLG2 | c.844T>A p.Y282N | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV66168332; called by muse, mutect2, varscan2
- FOXA1 | c.284G>C p.S95T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs201419897, COSV51645527; called by muse, mutect2
- GRIN2A | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473377043, COSV58030560; called by muse, mutect2, varscan2
- HEPHL1 | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59891493; called by muse, mutect2, varscan2
- MED23 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as COSV63432244; called by muse, mutect2, varscan2
- MIEF1 | c.1096A>T p.I366F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV57478764; called by muse, mutect2, varscan2
- PCDHA1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV65374021; called by muse, mutect2, varscan2
- REG3G | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV55449230; called by muse, mutect2, varscan2
- RTL4 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755353797, COSV61206302, COSV61207065; called by muse, mutect2, varscan2
- RTL5 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs755049099, COSV65452307; called by mutect2, varscan2
- SHOX | c.194A>T p.H65L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61860721; called by muse, mutect2, varscan2
- ZNF287 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs770221561, COSV67688069; called by muse, mutect2, varscan2
- CDH6 | c.2088C>A p.A696= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV54066209, COSV54068823; called by mutect2, varscan2
- CHD1L | c.2430T>C p.N810= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV63613773; called by muse, mutect2, varscan2
- SPRR2G | c.60G>A p.T20= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs1206815148, COSV64203040; called by muse, mutect2
- TMPRSS2 | c.1335G>A p.L445= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV59823023; called by muse, mutect2
